Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A2FM, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A2FM-01A (Primary Tumor).

D.O.B.:
MRN #:
Ref Physician

SPECIM.

Collected:
Received:
Reported:

Accession #:
Acct / Reg #:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Sentinel lymph nodes x2:

Small foci of metastatic carcinoma in the perinodal connective tissue.

These foci of metastatic carcinoma are not seen within the node.

Size: Approximately 0.5 cm.

These foci are identified on the H and E stain and confirmed by staining for cytokeratin CAM 5.2

B. Right breast:

Infiltrating mammary carcinoma. Size: 3 x 3 x 2.8 cm.

Architectural score: 3/3

Nuclear score: 2/3

Mitotic score: 1/3

Total score: 6/9 = grade II.

No significant component of in situ carcinoma.

Angio invasion not identified.

Ancillary studies were reported on the original needle biopsy and will not be repeated.

All surgical margins of excision are free of carcinoma.

The closest surgical margin is deep and is approximately 0.2 cm.

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Right breast cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

100-0-3
carcinoma, infiltrating lobular, NOS (per confirming email)
8520/3
Site: breast, NOS C50.9 per 6/10/11

SPECIMENS:

- A. Sentinel node x2
B. Right breast

SPECIMEN DATA

GROSS DESCRIPTION:

A. Container A is labeled and consists of two tan yellow firm fatty lymph nodes the largest 1.0 x 0.8 x 0.5 cm. Both nodes are sampled for frozen section and all tissue submitted in two cassettes designated as frozen section tissue as 1; all remaining tissue as 2.

B. Container B is labeled and consists of a 450 gram portion of right breast tissue, 20 x 15 x 5 cm with attached tan pink ellipse of skin, 18 x 8 cm displaying an eccentrically located raised nipple 1.0 cm in greatest dimension. The deep margin of the specimen has been inked and the specimen serially sectioned to reveal predominantly tan yellow lobular adipose tissue intermixed with a minimal amount of tan gray dense fibrous tissue. A gray white dense mass is found near the lateral aspect of the specimen 3 x 3 x 2.8 cm in greatest dimension which extends from 1 cm below the skin margin up to within 0.1 cm of the deep margin. No other lesions are grossly identified. Sectioning along the lateral margin of the specimen reveals no lymph nodes. Samples from the four quadrants of the breast tissue are submitted. Samples of the mass have been submitted for genomic studies in three cassettes. Representative sections are submitted in ten cassettes and are designated as follows: nipple submitted as 1; lesion as 2-5; deep margin 6; upper inner quadrant 7; upper outer as 8; lower inner 9; lower outer as 10.

E
Deep margin.

is 2.5 cm mass found 1 mm from the

Source: NCI Genomic Data Commons file e54fba3d-4e1a-4ab9-aa58-319756bbf1b4 (TCGA-AC-A2FM.83BA3E82-E8E4-4A70-ADEE-A1360940EECE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).